Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A28H, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A28H-01A (Primary Tumor).

Path (First Tumor)

Tumor Site:	Cecum Proximal		
Date of Cancer Sample Procurement:			
Histology:	Adenocarcinoma		
Description of other histology:			
Grade:	Poorly Differentiated		
Mucinous:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No	☐ Yes	☐ Unknown
Host Response:	None		
Crohn's like reaction	☒ None	☐ Yes	☐ Unknown
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown
Growth Pattern:	☐ Expansile	☒ Invasive	☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No	☐ Yes	☐ Unknown
Angiolymphatic Invasion:	☒ No	☐ Yes	☐ Unknown
Mutator Phenotype:	☒ No	☐ Yes	☐ Unknown
Number of Slides	2		
Garland Necrosis present:	☐ No	☒ Yes	☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	0		
Pathologist Comment:			

1CD-0-3

adenocarcinoma, NOS 8/40/3

Site: Cecum C18.0

5/3/11

HPV Discrepancy		
Case ID (circle):	QUALIFIED	UNQUALIFIED

Source: NCI Genomic Data Commons file 48d7da2a-c230-4627-93bf-c291ef472ddc (TCGA-DM-A28H.9DA1FAC8-4D16-4F59-A283-6E5093034816.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).